Somatic mutation profile of tumor specimen BA3029D (aliquot aq-BA3029D) from BEATAML1.0 case 2079, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.9 years (22,986 days).
Specimen BA3029D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) beb1ecea-63e6-4ca1-bedd-447720a4dd77.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2568D (Solid Tissue Normal), aliquot aq-BA2568D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ebdc252-0dc2-424b-b74c-f0e7205ed992

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 2, Frame Shift Ins 2, 5'UTR 1, RNA 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTN3 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 103/229 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); catalogued as rs759356391; called by muse, mutect2, varscan2
- APBB2 | c.955C>T p.R319W (on ENST00000295974 / NM_001166050.2; = p.R320W on NM_004307.2) | Missense Mutation (SNP) | VAF 122/271 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs538682911, COSV55954670; called by muse, mutect2, varscan2
- CCND3 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1405358214, COSV57827932, COSV57829953; called by muse, mutect2, varscan2
- CREB5 | c.1090G>C p.G364R (on ENST00000357727 / NM_182898.4; = p.G357R on NM_004904.3) | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV63221816; called by muse, mutect2, varscan2
- CRYBG2 | c.2384C>T p.S795F | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as rs1254078982; called by muse, mutect2, varscan2
- NBEAL2 | c.937A>G p.M313V | Missense Mutation (SNP) | VAF 63/134 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1423322450; called by muse, mutect2, varscan2
- NPM1 | c.863_864insCCTG p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 28/85 reads (33%) | catalogued as rs1554138189, COSV51543231, COSV51545499, COSV51554041, COSV51557774, COSV51563665; called by mutect2, pindel, varscan2
- SART1 | c.788T>C p.I263T | Missense Mutation (SNP) | VAF 76/174 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.321); catalogued as rs1444259709, COSV100409114; called by muse, mutect2, varscan2
- SLC4A2 | c.2074C>T p.R692C | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765272940; called by mutect2, varscan2
- ADAMTS6 | c.1522A>G p.R508G | Missense Mutation (SNP) | VAF 65/147 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- EMILIN3 | c.2125G>T p.G709C | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2
- RFC1 | c.1406_1407insA p.I470Yfs*2 | Frame Shift Ins (INS) | VAF 51/143 reads (36%) | called by mutect2, pindel, varscan2
- RIN3 | c.1954A>G p.K652E | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- TRAPPC2L | c.317_319del p.S106del | In Frame Del (DEL) | VAF 24/50 reads (48%) | called by mutect2, varscan2
- ADORA1 | c.888C>T p.R296= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs201811129, COSV99704644; called by muse, varscan2
- MUC17 | c.8109G>A p.L2703= | Silent (SNP) | VAF 41/92 reads (45%) | catalogued as COSV60284014; called by muse, mutect2, varscan2
- BTN3A2 | c.-122A>G | 5'UTR (SNP) | VAF 30/88 reads (34%) | called by muse, mutect2, varscan2
- NTM-AS1 | n.1772G>C | RNA (SNP) | VAF 29/80 reads (36%) | called by muse, mutect2
- XIAP | c.*5596C>A | 3'UTR (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
